Somatic mutation profile of tumor specimen TCGA-D8-A73X-01A (aliquot TCGA-D8-A73X-01A-11D-A32I-09) from TCGA case TCGA-D8-A73X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.7 years (19,607 days).
Specimen TCGA-D8-A73X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05442037-337a-4cb4-89b1-a6d66cef594f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A73X-10A (Blood Derived Normal), aliquot TCGA-D8-A73X-10A-21D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba1723b1-5b01-45b4-85e8-00c87e53d6c6

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 2, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP3M2 | c.1184A>G p.Y395C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs899150583, COSV99441760; called by muse, mutect2
- ASIC5 | c.1236G>A p.R412= | Splice Region (SNP) | VAF 17/78 reads (22%) | catalogued as COSV101611149; called by muse, mutect2, varscan2
- CELSR3 | c.4934C>T p.A1645V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs1427547973, COSV99374008; called by muse, mutect2
- CHD4 | c.2621G>A p.R874Q (on ENST00000357008 / NM_001363606.2; = p.R887Q on NM_001273.5) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100539595, COSV58902522; called by muse, mutect2
- CX3CR1 | c.476T>C p.L159S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); catalogued as COSV100843235; called by muse, mutect2, varscan2
- EIF3I | c.229C>A p.R77S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100557220, COSV100557250; called by muse, mutect2, varscan2
- FBXO38 | c.3259A>G p.I1087V (on ENST00000340253 / NM_205836.3; = p.I1012V on NM_030793.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99693606; called by muse, mutect2, varscan2
- FCGBP | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs764331085; called by mutect2, varscan2
- FMO1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100707692, COSV100707694; called by muse, mutect2
- KIF5B | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs1179830901, COSV100192052; called by muse, mutect2, varscan2
- KIFBP | c.539_541del p.P180del | In Frame Del (DEL) | VAF 29/57 reads (51%) | catalogued as rs757514844; called by pindel, varscan2
- KLHDC7A | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1261399650, COSV68769211; called by muse, mutect2, varscan2
- MAP3K1 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV68129142; called by muse, mutect2, varscan2
- MAP3K1 | c.4321G>A p.E1441K | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101266998; called by muse, mutect2, varscan2
- NEB | c.10210G>A p.V3404I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.415); catalogued as COSV50805956, COSV99424858; called by muse, mutect2, varscan2
- NEGR1 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164481, COSV60831631; called by muse, mutect2, varscan2
- NUAK1 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759029750, COSV54602823; called by muse, mutect2, varscan2
- OR10A3 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV100660297; called by muse, mutect2
- PDLIM3 | c.299G>A p.R100H (on ENST00000284770 / NM_001257963.1; = p.R267H on NM_014476.6) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539118406, COSV99507326; called by muse, mutect2, varscan2
- PIWIL1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144603967, COSV55345055; called by muse, mutect2, varscan2
- PTCH2 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV100942178; called by muse, mutect2, varscan2
- PTK2 | c.1166T>C p.V389A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV100570564; called by muse, mutect2, varscan2
- REN | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV65817589, COSV99689607; called by muse, mutect2, varscan2
- SYNE1 | c.3127G>T p.D1043Y (on ENST00000367255 / NM_182961.4; = p.D1050Y on NM_033071.3) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV99569946; called by muse, mutect2, varscan2
- TBC1D9B | c.2965G>C p.E989Q (on ENST00000356834 / NM_198868.3; = p.E972Q on NM_015043.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100783572; called by muse, mutect2, varscan2
- TNNT1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52571541; called by muse, varscan2
- UHRF1BP1 | c.3005T>C p.V1002A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99512092; called by muse, mutect2, varscan2
- TMEM204 | c.14_15del p.R5Tfs*67 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by pindel, varscan2
- ASIC2 | c.1491C>T p.N497= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs200452478; called by muse, mutect2, varscan2
- FRMPD3 | c.3354C>T p.G1118= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs766873031, COSV52187284; called by muse, mutect2, varscan2
- IKBKE | c.1167G>T p.G389= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV100898308; called by muse, mutect2, varscan2
- INTS5 | c.1392G>A p.P464= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs777523172, COSV57952184; called by muse, mutect2, varscan2
- ITSN2 | c.2493A>G p.L831= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100743810; called by muse, mutect2, varscan2
- PCDHA1 | c.2232G>A p.A744= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1554118281, COSV100974376, COSV100974390; called by muse, mutect2, varscan2
- PDZK1IP1 | c.105C>T p.I35= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs1343099761, COSV53743920; called by muse, mutect2, varscan2
- SYNE1 | c.26208C>T p.S8736= (on ENST00000367255 / NM_182961.4; = p.S8688= on NM_033071.3) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs770690488, COSV99569943; called by muse, mutect2, varscan2
- TMPRSS4 | c.1005T>C p.N335= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV101449410; called by muse, mutect2, varscan2
- TPH1 | c.153A>G p.R51= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100000950; called by muse, mutect2, varscan2
- ZNF101 | c.583A>C p.R195= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100543581; called by muse, mutect2, varscan2
